Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A55R, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A55R-01A (Primary Tumor).

[page 1 of 9]
ICD-O-3

path Adenocarcinoma, NOS
8140/3

~~CCF~~ Adenocarcinoma, Solid NOS
8230/3

Site @ Lung, upper lobe
C34.1

QW 1/14/13

Procedure Location:

PATHOLOGY SURGICAL

Results

Status: Final result

Entry Date

[page 2 of 9]
Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report
format

FINAL DIAGNOSIS

A. (Level five lymph node; biopsy): Two lymph nodes, negative for
malignancy.

[page 3 of 9]
B. (Level eleven lymph node; biopsy): One lymph node, negative for malignancy.

C. (Lung, left upper lobe; lobectomy): Invasive moderately differentiated adenocarcinoma, measuring 2.2 cm in greatest dimension. Margins of resection free of tumor. Six peribronchial lymph nodes, negative for malignancy. Stage pT1b (PL 0) N0. See note.

D. (Level seven lymph node; biopsy): One lymph node, negative for malignancy.

INTRAOPERATIVE CONSULTATION

C. FROZEN:LEFT UPPER LOBECTOMY FROZEN ON THE TUMOR: Infiltrating carcinoma, favor squamous cell carcinoma. (C91, TP, smear)

NOTE

[page 4 of 9]
C. Immunohistochemical stains show that the tumor is positive for cytokeratin 7 and TTF-1 and negative for cytokeratin 5,6 and P63, supporting the diagnosis. Immunohistochemistry controls are examined and show appropriate reactivity.

Lung Cancer Summary

Specimen type: Left upper lobectomy

Tumor location: Left upper lobe

Tumor size: 2.2 x 1.7 x 1.6 cm

Histologic type: Adenocarcinoma

Histologic grade: 2

Status of margins:

Bronchial: Negative

Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral/Parietal pleural invasion: Absent

Lymphatic vascular invasion: Absent

[page 5 of 9]
Lymph node status: Negative

Extension into other structures: Absent

Non-neoplastic pathology: N/A

TMN stage: Stage pT1b (PL 0) NO

GROSS DESCRIPTION

A. The specimen is labeled level five lymph node. Received fresh are two possible black lymph nodes (1.2 and 1.3 cm in greatest dimension). The larger node is bisected in cassette A1 and the smaller is submitted intact in cassette A2.

B. The specimen is labeled level eleven lymph node. Received fresh is a single 2.5 x 0.9 x 0.4 cm possible lymph node. The specimen is entirely submitted intact in cassette B1.

C. The specimen is labeled left upper lobectomy, frozen on tumor. Received fresh for frozen section is a 22.5 x 11.2 x 3.7 cm left upper lobectomy specimen. Serial sectioning reveals a well circumscribed, firm, gray-white mass measuring 2.2 x 1.7 x 1.6 cm that is causing pleural puckering and is closest at 8 cm from the bronchial and vascular margins. The pleura around

[page 6 of 9]
the mass is inked blue. A representative section is submitted for frozen section analysis with remnants wrapped and placed in cassette C91. Touch prep and smear prepared. Additional representative sections are submitted as follows: C1, bronchial and vascular margin; C2, peribronchial lymph node; C3 and C4, mass with inked pleura; C5, mass with adjacent grossly normal lung; and C6, lung away from mass.

D. The specimen is labeled level seven lymph node. Received fresh is a single 0.6 x 0.5 x 0.2 cm lymph node with surrounding fibroadipose tissue. The entire specimen is submitted in cassette D1.

SPECIMEN(S) RECEIVED

A: LEVEL FIVE LYMPH NODE

B: LEVEL ELEVEN LYMPH NODE

C: FROZEN:LEFT UPPER LOBECTOMY FROZEN ON THE TUMOR

D: LEVEL SEVEN LYMPH NODE

* The above listed tests (if any) were developed and the performance characteristics determined by Pathology. These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

[page 7 of 9]
DIAGNOSIS: LUNG CANCER; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC,
THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.3

CPT(s): A: 88307

B: 88305

C: 88309, 88331, 88334, 88334, 88342 p63, 88342 ck5,6, 88342 ttf1, 88342 ck7

D: 88305

The attending pathologist was physically present when this specimen was
diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

- Lab and Collection Information

[page 8 of 9]
PATHOLOGY SURGICAL

Pathology

Procedure Location:

Diagnostic discrepancy from provided that
states TCGA tumor to be solid adenocarcinoma.

Print Malignancy History		
Dual/Synchronous Malignancy Noted		

[page 9 of 9]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____

Completed By (Interviewer Name on OpenClinica): _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Invasive moderately differentiated Adenocarcinoma .	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Solid.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Path Report does not subtype .	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file 2c729e19-ae3e-4e56-ac63-cfd8a5392f38 (TCGA-NJ-A55R.726A5F6E-4592-49AA-976F-556CABABDD3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).